Gene-level copy-number profile of tumor specimen C3N-03619-02 from CPTAC case C3N-03619, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.6 years (21,757 days).
Specimen C3N-03619-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d260f38f-cc9f-4d98-af72-ebddc2d518ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03619-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/eff65155-f028-46bf-9673-138aeab90721

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 17,126; copy number 2: 35,386; copy number 3: 4,933; copy number 4: 902; copy number 5: 141; copy number 6: 240; copy number 7: 89; copy number 8: 11; copy number 10: 25; copy number 13: 1; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:41,687,868–41,688,033, 1 gene (within-gene range 0–1): AC099537.1.
- chr3:75,384,059–75,599,673, 12 genes (within-gene range 0–2): AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P.
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr8:12,341,426–12,345,776, 1 gene: DEFB108E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 509 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:89,754,620–106,770,207, 407 genes, copy number 5–20 (broad region; genes not listed).
- chr8:38,269,704–38,382,272, 1 gene, copy number 8 (within-gene range 2–8): NSD3.
- chr8:38,335,981–38,704,855, 11 genes, copy number 8–13: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr10:50,655,967–52,298,423, 18 genes, copy number 7 (within-gene range 4–7): BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T.
- chr10:52,389,112–52,852,703, 5 genes, copy number 7: RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA.
- chr11:57,861,948–58,624,639, 39 genes, copy number 7 (within-gene range 2–7): OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1.
- chr11:69,641,156–70,436,584, 27 genes, copy number 7: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr18:20,946,906–21,111,813, 1 gene, copy number 5: ROCK1.

Autosomal genes at a single copy (total copy number 1): 14,808. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
